Somatic mutation profile of tumor specimen TCGA-EE-A180-06A (aliquot TCGA-EE-A180-06A-11D-A21A-08) from TCGA case TCGA-EE-A180, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.1 years (28,165 days).
Specimen TCGA-EE-A180-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93fc797c-8641-45c0-b4db-a875c5ecf1d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A180-10B (Blood Derived Normal), aliquot TCGA-EE-A180-10B-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfe24dac-9f02-43f4-8234-319a40888e96

The open-access MAF lists 633 somatic variants for this specimen: 425 protein-altering or splice-affecting, 195 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 382, Silent 195, Nonsense Mutation 27, Frame Shift Del 5, Splice Site 4, Intron 4, RNA 4, Splice Region 3, 3'Flank 2, Nonstop Mutation 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.874A>G p.K292E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV62713055; called by muse, mutect2, varscan2
- OXA1L | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 152/257 reads (59%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen benign (0.208); catalogued as rs773412250, COSV53536555; called by muse, mutect2, varscan2
- PTPN11 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 150/267 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121918457, CM021672, COSV61005439; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SDHD | c.479G>T p.*160Lext*3 | Nonstop Mutation (SNP) | VAF 45/60 reads (75%) | catalogued as rs201372601, CM141637, COSV65019649, COSV65019826; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 51/98 reads (52%) | catalogued as rs5030829, CM156382, CM941369, COSV56543353, COSV56543426; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 133/354 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374354826, COSV100206713, COSV60200198; called by muse, mutect2, varscan2
- ABCA7 | c.2308C>T p.R770W | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs557493808, COSV54026446; called by muse, mutect2, varscan2
- ABCB5 | c.2162G>A p.G721E (on ENST00000404938 / NM_001163941.2; = p.G276E on NM_178559.6) | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV51718568; called by muse, mutect2, varscan2
- ACACB | c.7195A>G p.I2399V | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV58143878; called by muse, mutect2, varscan2
- ACSL6 | c.1424G>A p.W475* (on ENST00000379240; = p.W500* on NM_015256.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 238/409 reads (58%) | catalogued as COSV57303893; called by muse, mutect2, varscan2
- ACSM1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV54633527; called by muse, mutect2, varscan2
- ACTN2 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 24/455 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781559530, COSV63971955; called by muse, mutect2
- ACVR2B | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 264/408 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61703546; called by muse, mutect2, varscan2
- ACVRL1 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV66360833; called by muse, varscan2
- ADAMTS6 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 61/90 reads (68%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as COSV66863773; called by muse, varscan2
- ADAMTSL4 | c.314A>C p.Q105P | Missense Mutation (SNP) | VAF 159/232 reads (69%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); catalogued as COSV55006099; called by muse, mutect2, varscan2
- ADCY8 | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs371754667, COSV53910739; called by muse, mutect2, varscan2
- ADGRB3 | c.4406C>T p.P1469L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53250831; called by muse, mutect2, varscan2
- ADGRD1 | c.321T>G p.F107L | Missense Mutation (SNP) | VAF 120/177 reads (68%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as COSV55454753; called by muse, mutect2, varscan2
- ADRA1B | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 109/277 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761487660, COSV60700924; called by muse, mutect2, varscan2
- AFF3 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57869264; called by muse, mutect2, varscan2
- AGAP6 | c.1109C>T p.P370L (on ENST00000374056 / NM_001365867.1; = p.P393L on NM_001077665.2) | Missense Mutation (SNP) | VAF 62/199 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV65018287; called by muse, mutect2, varscan2
- AHRR | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs201569519, COSV57084895; called by muse, mutect2, varscan2
- ALG10 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762214045, COSV56791818; called by muse, mutect2, varscan2
- AMBRA1 | c.1540C>T p.Q514* (on ENST00000458649 / NM_001367468.1; = p.Q424* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 76/137 reads (55%) | catalogued as COSV54061112; called by muse, mutect2, varscan2
- AMER3 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.47); catalogued as COSV58466951; called by muse, mutect2, varscan2
- AMMECR1 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as COSV53319826; called by muse, mutect2, varscan2
- ANKDD1A | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV60352922; called by muse, mutect2, varscan2
- ANKRD30A | c.2527G>A p.D843N (on ENST00000611781; = p.D787N on NM_052997.2) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.043); catalogued as COSV64608669; called by muse, mutect2, varscan2
- ANKRD35 | c.1690C>A p.Q564K | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV62911374; called by muse, mutect2, varscan2
- ANO2 | c.280A>G p.K94E (on ENST00000356134 / NM_001278597.3; = p.K98E on NM_001278596.3) | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59039148; called by muse, mutect2, varscan2
- AP4B1 | c.1210A>G p.T404A | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as COSV56726639; called by muse, mutect2, varscan2
- APBB2 | c.2114G>A p.R705Q (on ENST00000295974 / NM_001166050.2; = p.R706Q on NM_004307.2) | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55960418; called by muse, mutect2, varscan2
- APOF | c.754G>T p.G252W | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58476964; called by muse, mutect2, varscan2
- ARHGAP25 | c.1586G>A p.G529E (on ENST00000409202 / NM_001007231.3; = p.G521E on NM_014882.3) | Missense Mutation (SNP) | VAF 93/195 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV54907452; called by muse, mutect2, varscan2
- ARHGEF10 | c.479C>T p.P160L (on ENST00000398564; = p.P136L on NM_014629.4) | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs779851603, COSV50670587; called by muse, mutect2, varscan2
- ARHGEF11 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 100/149 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63815208; called by muse, mutect2, varscan2
- ASTE1 | c.1618C>T p.H540Y | Missense Mutation (SNP) | VAF 163/178 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53910077; called by muse, mutect2, varscan2
- ATP13A5 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 118/414 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148527761, COSV60868562; called by muse, varscan2
- ATP2A1 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as COSV63922126; called by muse, mutect2, varscan2
- ATP2B2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 388/605 reads (64%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV100659454, COSV59505706; called by muse, mutect2, varscan2
- AUTS2 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 128/257 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); catalogued as rs747841534, COSV100715774; called by muse, mutect2, varscan2
- BCL11B | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV61738549; called by muse, mutect2, varscan2
- BNIP1 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs1230003408, COSV51571817; called by muse, mutect2, varscan2
- BPIFB2 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs1216041150, COSV50069656, COSV99401517; called by muse, mutect2, varscan2
- BRINP1 | c.112T>A p.F38I | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); catalogued as COSV56310780; called by muse, mutect2, varscan2
- BSN | c.4738C>T p.P1580S | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.763); catalogued as COSV56522752; called by muse, mutect2, varscan2
- C11orf16 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 193/372 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.117); catalogued as COSV58168822; called by muse, mutect2, varscan2
- C12orf50 | c.369G>A p.G123= | Splice Region (SNP) | VAF 36/56 reads (64%) | catalogued as rs1348867434, COSV53898133; called by muse, mutect2, varscan2
- C1orf94 | c.1714G>A p.G572R (on ENST00000488417 / NM_001134734.2; = p.G382R on NM_032884.5) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV64915347; called by muse, mutect2, varscan2
- C6orf118 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 84/155 reads (54%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as COSV57818171; called by muse, mutect2, varscan2
- C7 | c.2479G>A p.G827R | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV57479422; called by muse, mutect2, varscan2
- C8B | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.029); catalogued as COSV64777473; called by muse, mutect2, varscan2
- CACNA2D3 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55512725, COSV55572983; called by muse, mutect2, varscan2
- CACNA2D3 | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55573001; called by muse, mutect2, varscan2
- CADM3 | c.685G>A p.V229I (on ENST00000368125 / NM_001127173.3; = p.V263I on NM_021189.5) | Missense Mutation (SNP) | VAF 125/191 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.338); catalogued as COSV63687001; called by muse, mutect2, varscan2
- CASR | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 61/68 reads (90%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.656); catalogued as COSV56140690; called by muse, mutect2, varscan2
- CATSPERG | c.2949G>A p.W983* | Nonsense Mutation (SNP) | VAF 121/468 reads (26%) | catalogued as COSV53052685; called by muse, mutect2, varscan2
- CC2D1A | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV58785717; called by muse, mutect2, varscan2
- CCDC105 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52965377; called by muse, mutect2, varscan2
- CCDC185 | c.1045C>G p.Q349E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.085); catalogued as COSV100838841, COSV64821681; called by muse, mutect2
- CCDC59 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50261371; called by muse, mutect2, varscan2
- CCDC63 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 95/152 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57526812; called by muse, mutect2, varscan2
- CCN6 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1438976078, COSV100036940; called by muse, mutect2, varscan2
- CCT6B | c.1553T>C p.V518A | Missense Mutation (SNP) | VAF 138/153 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs769684310, COSV58491395; called by muse, mutect2, varscan2
- CD300C | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 126/133 reads (95%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as rs774356354, COSV58169984; called by muse, mutect2, varscan2
- CDCA2 | c.3072A>T p.*1024Yext*42 | Nonstop Mutation (SNP) | VAF 32/106 reads (30%) | catalogued as COSV57948091; called by muse, mutect2, varscan2
- CDH12 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 153/256 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs765231841, COSV66389349; called by muse, mutect2, varscan2
- CDH9 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 100/297 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV50276442, COSV50404628; called by muse, varscan2
- CDK17 | c.580A>G p.K194E | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54132689; called by muse, mutect2, varscan2
- CDK6 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.171); catalogued as COSV56012165; called by muse, mutect2, varscan2
- CEACAM5 | c.2093G>T p.G698V | Missense Mutation (SNP) | VAF 229/747 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.113); catalogued as COSV55754395; called by muse, mutect2, varscan2
- CEACAM6 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 104/164 reads (63%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as rs782604875, COSV52268918; called by muse, mutect2
- CELF4 | c.912G>A p.M304I | Missense Mutation (SNP) | VAF 101/161 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV58452048; called by muse, mutect2, varscan2
- CELF5 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 160/278 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV53014410; called by muse, mutect2, varscan2
- CEP97 | c.2545C>T p.Q849* | Nonsense Mutation (SNP) | VAF 56/254 reads (22%) | catalogued as rs1375088405, COSV59127377; called by muse, mutect2, varscan2
- CFHR5 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs748341345, COSV56818591; called by muse, mutect2, varscan2
- CHAT | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs780662703, COSV60325177; called by muse, mutect2, varscan2
- CHD4 | c.2785C>T p.Q929* (on ENST00000357008 / NM_001363606.2; = p.Q942* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 38/179 reads (21%) | catalogued as COSV100537583; called by muse, mutect2, varscan2
- CHSY1 | c.1685A>G p.N562S | Missense Mutation (SNP) | VAF 68/116 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs746282806, COSV54255540; called by muse, mutect2, varscan2
- CLN3 | c.482C>T p.S161F (on ENST00000360019 / NM_001286104.2; = p.S185F on NM_000086.2) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100343176; called by muse, mutect2, varscan2
- CLPSL1 | c.222+1G>A p.X74_splice | Splice Site (SNP) | VAF 27/126 reads (21%) | catalogued as COSV65815133; called by muse, mutect2, varscan2
- CLPTM1 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 89/255 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61612800; called by muse, mutect2, varscan2
- CMTM2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1447016439, COSV51749523; called by muse, mutect2, varscan2
- CNTLN | c.2564A>G p.N855S | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.13); catalogued as rs1216725110, COSV52093420; called by muse, mutect2
- CNTN5 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as rs1398463099, COSV54329471; called by muse, mutect2, varscan2
- CNTN6 | c.2162G>C p.W721S | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100610400, COSV63172359; called by muse, mutect2, varscan2
- CNTN6 | c.2163G>A p.W721* | Nonsense Mutation (SNP) | VAF 34/159 reads (21%) | catalogued as COSV100611863, COSV63168994; called by muse, mutect2, varscan2
- COL15A1 | c.2552T>A p.F851Y | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); catalogued as COSV66644783, COSV66648419; called by muse, mutect2, varscan2
- COL1A1 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 369/416 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72645335, CM070718, COSV56808755; called by muse, mutect2, varscan2
- COL21A1 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as rs373575633, COSV99056775; called by muse, mutect2, varscan2
- CORO2B | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 88/149 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55956499; called by muse, mutect2, varscan2
- CR1 | c.5498G>A p.W1833* | Nonsense Mutation (SNP) | VAF 385/553 reads (70%) | catalogued as COSV65462178; called by muse, mutect2, varscan2
- CSMD2 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs1431374350, COSV53952180; called by muse, mutect2, varscan2
- CUBN | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100913673, COSV64724826; called by muse, mutect2, varscan2
- CUL2 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV101038990, COSV66080568; called by muse, mutect2, varscan2
- CYP3A7 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100312601; called by muse, mutect2, varscan2
- CYTH4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as rs865913340, COSV50635280; called by muse, mutect2, varscan2
- CYTIP | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as rs867898942, COSV51632634; called by muse, mutect2, varscan2
- DCDC1 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs776704634, COSV60835487; called by muse, mutect2, varscan2
- DEFB116 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101269229, COSV68722380; called by muse, mutect2, varscan2
- DES | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 88/185 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV64660940; called by muse, mutect2, varscan2
- DGKI | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 70/121 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV55970706; called by muse, mutect2, varscan2
- DNAAF6 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as COSV60496688; called by muse, mutect2, varscan2
- DNAH10 | c.4108C>T p.P1370S (on ENST00000409039; = p.P1309S on NM_207437.3) | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as rs763449366, COSV68999810; called by muse, mutect2, varscan2
- DNAH7 | c.4630G>A p.D1544N | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56771762, COSV56780975; called by muse, mutect2, varscan2
- DNAH7 | c.4510G>A p.A1504T | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195633870, COSV56780986; called by muse, mutect2, varscan2
- DNM3 | c.2336G>A p.R779K (on ENST00000355305 / NM_001350206.2; = p.R773K on NM_015569.5) | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV62465331; called by muse, mutect2, varscan2
- DOCK4 | c.4606G>A p.D1536N | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs1402703457, COSV70242134; called by muse, mutect2, varscan2
- DPH7 | c.998C>T p.S333L | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1441509347, COSV53023612; called by muse, mutect2, varscan2
- DPP7 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs1473473376, COSV65371781; called by muse, mutect2, varscan2
- DSC3 | c.2354G>A p.G785E | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs551626331, COSV64574930; called by muse, mutect2, varscan2
- DSCAM | c.3734C>T p.S1245F | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68021687; called by muse, mutect2, varscan2
- DSG2 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV55202112; called by muse, mutect2, varscan2
- DST | c.6220G>A p.G2074R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99753121; called by muse, mutect2, varscan2
- E2F2 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs756515833, COSV62276498, COSV62276725; called by muse, mutect2, varscan2
- ECM1 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 474/667 reads (71%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs760636611, COSV60873142; called by muse, mutect2, varscan2
- EDN1 | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 136/149 reads (91%) | catalogued as COSV65081016; called by muse, mutect2, varscan2
- EFHD1 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745364469, COSV51132378; called by muse, mutect2, varscan2
- EIF2AK2 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV51798641; called by muse, mutect2, varscan2
- ENTPD6 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV61750914, COSV61752272; called by muse, mutect2, varscan2
- EPHA7 | c.2785G>T p.G929* | Nonsense Mutation (SNP) | VAF 41/96 reads (43%) | catalogued as COSV65189714; called by muse, mutect2, varscan2
- EPHA7 | c.2171G>A p.R724K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV65189723; called by muse, mutect2, varscan2
- ERAL1 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 207/220 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1367253715, COSV54740259; called by muse, mutect2, varscan2
- ERICH3 | c.4379G>A p.G1460E | Missense Mutation (SNP) | VAF 104/218 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV58615792; called by muse, mutect2, varscan2
- ERICH3 | c.3674G>A p.G1225E | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV58610360; called by muse, mutect2, varscan2
- ERICH3 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as COSV100445538, COSV58615805; called by muse, mutect2, varscan2
- ERN1 | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 84/93 reads (90%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as rs1168524911, COSV70504391; called by muse, mutect2, varscan2
- EXOC3L2 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as rs780283148, COSV52974372; called by muse, mutect2, varscan2
- EXT2 | c.587C>T p.P196L (on ENST00000343631; = p.P229L on NM_000401.3) | Missense Mutation (SNP) | VAF 114/250 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV59154165; called by muse, mutect2, varscan2
- EZH2 | c.1276C>T p.P426S (on ENST00000460911 / NM_001203247.2; = p.P431S on NM_004456.5) | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV57450804, COSV57460840; called by muse, mutect2, varscan2
- F11 | c.405A>T p.E135D | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.698); catalogued as COSV53009167; called by muse, mutect2, varscan2
- FAM171B | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV59007503; called by muse, mutect2, varscan2
- FAT3 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 128/135 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408408990, COSV53116526; called by muse, mutect2, varscan2
- FHL5 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs1449031326, COSV58736537; called by muse, mutect2, varscan2
- FKBP15 | c.3101C>T p.S1034F | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); catalogued as COSV53038588; called by muse, mutect2, varscan2
- FLG | c.8840C>T p.S2947F | Missense Mutation (SNP) | VAF 93/625 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV100911258; called by muse, mutect2, varscan2
- FNDC11 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs769043567, COSV64443301; called by muse, mutect2, varscan2
- FOXD4L5 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs1303098671, COSV66241082; called by muse, mutect2, varscan2
- FOXK1 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61068180; called by muse, mutect2, varscan2
- FOXO3 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 95/256 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV59630763; called by muse, mutect2, varscan2
- FYB2 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1026583931, COSV58586914, COSV58588374; called by muse, mutect2, varscan2
- GABRB1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 134/310 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54972105; called by muse, mutect2, varscan2
- GABRG1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239800695, COSV54951118; called by muse, mutect2, varscan2
- GAREM1 | c.2356C>T p.P786S (on ENST00000269209 / NM_001242409.2; = p.P785S on NM_022751.3) | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.253); catalogued as COSV52514934; called by muse, mutect2, varscan2
- GIMAP1 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV56189529; called by muse, mutect2, varscan2
- GJA5 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 200/323 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54783114, COSV99605717; called by muse, mutect2, varscan2
- GJB5 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 93/191 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs758744839, COSV100258313, COSV58356937; called by muse, mutect2, varscan2
- GPX3 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.199); catalogued as COSV59309694; called by muse, mutect2, varscan2
- GSTCD | c.619G>A p.G207R (on ENST00000360505 / NM_001031720.3; = p.G120R on NM_024751.3) | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs193103492, COSV64735246; called by muse, mutect2, varscan2
- HDAC9 | c.493A>T p.K165* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV67783275; called by muse, mutect2, varscan2
- HECW1 | c.3370C>T p.R1124C | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762675068, COSV67830741; called by muse, mutect2, varscan2
- HEPHL1 | c.2746G>A p.G916R | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (0.32); PolyPhen benign (0.068); catalogued as rs761903583, COSV59895518; called by muse, mutect2, varscan2
- HHIPL2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 110/582 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58564422; called by muse, mutect2, varscan2
- HHIPL2 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 187/257 reads (73%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as COSV58567224; called by muse, mutect2, varscan2
- HK3 | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV52843637; called by muse, mutect2, varscan2
- HOOK1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs367708992; called by muse, mutect2, varscan2
- HOXA6 | c.14T>C p.F5S | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56074540; called by muse, mutect2, varscan2
- HPS4 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 212/382 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as COSV61105066; called by muse, mutect2
- HS6ST2 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 48/50 reads (96%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs267606357, COSV63713124; called by muse, mutect2, varscan2
- HTR3A | c.220-1G>A p.X74_splice | Splice Site (SNP) | VAF 86/98 reads (88%) | catalogued as rs1381002800, COSV55471080; called by muse, mutect2, varscan2
- IGHM | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 101/325 reads (31%) | SIFT tolerated (0.23); catalogued as rs369884599; called by muse, mutect2, varscan2
- IGHV4-59 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.33); catalogued as rs782666152; called by mutect2, varscan2
- IGLV4-60 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as rs900902461, COSV66503725; called by muse, mutect2, varscan2
- INO80 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV62741964; called by muse, mutect2, varscan2
- INSRR | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 110/175 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV63872292; called by muse, mutect2, varscan2
- IQCA1 | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1309388078, COSV54510811; called by muse, mutect2, varscan2
- IQGAP1 | c.2527C>T p.Q843* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV51590124; called by muse, mutect2, varscan2
- IQGAP3 | c.3057-1G>A p.X1019_splice | Splice Site (SNP) | VAF 17/92 reads (18%) | catalogued as COSV63253986; called by muse, mutect2, varscan2
- ITGA4 | c.2357C>T p.S786L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101223211; called by muse, mutect2, varscan2
- JAKMIP1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as rs778487667, COSV51524422; called by muse, mutect2, varscan2
- JAKMIP2 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 148/351 reads (42%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.584); catalogued as COSV54613696; called by muse, mutect2, varscan2
- KCNC2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54377528; called by muse, mutect2, varscan2
- KCNH5 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as rs372872099; called by muse, mutect2, varscan2
- KIAA1549L | c.4561C>T p.P1521S (on ENST00000321505; = p.P1818S on NM_012194.3) | Missense Mutation (SNP) | VAF 150/383 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58595146; called by muse, mutect2, varscan2
- KIF16B | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.048); catalogued as COSV61712560; called by muse, mutect2, varscan2
- KLF11 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59940607; called by muse, mutect2, varscan2
- KLHL8 | c.1588C>T p.R530* | Nonsense Mutation (SNP) | VAF 34/105 reads (32%) | catalogued as rs780178586, COSV56746904; called by muse, mutect2, varscan2
- KMT2D | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.875); catalogued as rs201896284, COSV56477579; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT78 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV58852194; called by muse, mutect2, varscan2
- LAMA2 | c.3620C>T p.T1207I | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as COSV101370254; called by muse, varscan2
- LAMB3 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.283); catalogued as COSV50525316; called by muse, mutect2, varscan2
- LAMB4 | c.3898C>T p.L1300F | Missense Mutation (SNP) | VAF 97/383 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52728697; called by muse, mutect2, varscan2
- LCT | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV51556054; called by muse, mutect2, varscan2
- LILRB1 | c.808C>T p.P270S (on ENST00000427581; = p.P234S on NM_006669.6) | Missense Mutation (SNP) | VAF 98/184 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.856); catalogued as rs780318750, COSV61119013; called by muse, mutect2, varscan2
- LMO7 | c.2644C>T p.P882S (on ENST00000357063; = p.P563S on NM_005358.5) | Missense Mutation (SNP) | VAF 229/235 reads (97%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs773245524, COSV58545702; called by muse, mutect2, varscan2
- LRRC4B | c.2083C>T p.H695Y | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.242); catalogued as COSV65350651; called by muse, mutect2
- LRRC4C | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53435703, COSV99539818; called by muse, mutect2, varscan2
- LRRTM3 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.557); catalogued as COSV63670713; called by muse, mutect2, varscan2
- LTBP3 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100099269; called by muse, varscan2
- LTF | c.1676G>A p.G559E | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51611296; called by muse, mutect2, varscan2
- MAGEA6 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 89/96 reads (93%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV61449201; called by muse, mutect2, varscan2
- MAGEA6 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 111/118 reads (94%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs782047644, COSV61449367; called by muse, mutect2, varscan2
- MAGEB3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 31/32 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV64397638; called by muse, mutect2, varscan2
- MALT1 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as COSV61936195; called by muse, mutect2, varscan2
- MAN2B2 | c.2110T>C p.Y704H | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53456108; called by muse, mutect2, varscan2
- MARK2 | c.1859C>T p.P620L (on ENST00000402010 / NM_001039469.2; = p.P565L on NM_004954.5) | Missense Mutation (SNP) | VAF 118/344 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV59287988; called by muse, mutect2, varscan2
- MARVELD2 | c.161A>G p.Q54R | Missense Mutation (SNP) | VAF 116/210 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as COSV57782009; called by muse, mutect2, varscan2
- MAVS | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.903); catalogued as rs1206774160, COSV63927451, COSV63927478; called by muse, mutect2, varscan2
- MC2R | c.645G>A p.M215I | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV59617261; called by muse, mutect2, varscan2
- MED16 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 123/218 reads (56%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1424395754, COSV54130940; called by muse, mutect2, varscan2
- MFHAS1 | c.1452T>G p.Y484* | Nonsense Mutation (SNP) | VAF 42/160 reads (26%) | catalogued as COSV52286236; called by muse, mutect2, varscan2
- MGAM | c.5398G>A p.E1800K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs267601328, COSV72073671; called by muse, mutect2, varscan2
- MMP10 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 69/75 reads (92%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54247449; called by muse, mutect2, varscan2
- MMP11 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 79/139 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53156310; called by muse, mutect2, varscan2
- MMP2 | c.1610G>A p.G537E | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as COSV54604596, COSV54606146; called by muse, mutect2, varscan2
- MSR1 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs1296533085, COSV50527772; called by muse, mutect2, varscan2
- MUC16 | c.25679C>T p.S8560F | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV67477061, COSV67487606; called by muse, mutect2, varscan2
- MUC6 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV70149004; called by muse, mutect2
- MXRA5 | c.3490C>T p.H1164Y | Missense Mutation (SNP) | VAF 112/128 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV54246826; called by muse, mutect2, varscan2
- MYH7 | c.4996G>A p.D1666N | Missense Mutation (SNP) | VAF 108/161 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs747993770, COSV62518404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO7A | c.4070C>T p.P1357L | Missense Mutation (SNP) | VAF 86/340 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68686695; called by muse, mutect2, varscan2
- MYOM1 | c.4849G>A p.D1617N | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as rs1321034428, COSV55299409; called by muse, mutect2, varscan2
- NAE1 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51978043; called by muse, mutect2, varscan2
- NAIP | c.587A>C p.Q196P | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52002548; called by muse, mutect2, varscan2
- NAT16 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV55865513; called by muse, mutect2, varscan2
- NBAS | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55734696; called by muse, mutect2, varscan2
- NCKAP5L | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.339); catalogued as rs1417888289, COSV60132771; called by muse, mutect2, varscan2
- NDFIP1 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 91/181 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.717); catalogued as COSV54076057; called by muse, mutect2, varscan2
- NELL1 | c.1844A>G p.N615S | Missense Mutation (SNP) | VAF 83/320 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54313597; called by muse, mutect2, varscan2
- NELL2 | c.2443G>A p.E815K | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.899); catalogued as rs267603468, COSV61573921; called by muse, mutect2, varscan2
- NEUROD4 | c.734G>A p.S245N | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT tolerated (0.72); PolyPhen benign (0.428); catalogued as rs754054780, COSV54470635; called by muse, mutect2, varscan2
- NF1 | c.3774G>A p.W1258* | Nonsense Mutation (SNP) | VAF 283/324 reads (87%) | catalogued as COSV62217056; called by muse, mutect2, varscan2
- NMNAT3 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs774032862, COSV56158540; called by muse, mutect2, varscan2
- NOS1 | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 138/222 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs769811727, COSV57609906; called by muse, mutect2, varscan2
- NOS1AP | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 100/420 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62632528; called by muse, mutect2, varscan2
- NOVA1 | c.806del p.G269Dfs*21 | Frame Shift Del (DEL) | VAF 59/211 reads (28%) | catalogued as COSV99948408; called by mutect2, pindel, varscan2
- NPAS4 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 176/281 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV60652265; called by muse, mutect2, varscan2
- NR1D2 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56993388; called by muse, mutect2, varscan2
- NRXN1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV68002117, COSV68014469; called by muse, mutect2, varscan2
- NSUN7 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (1); PolyPhen probably damaging (0.959); catalogued as COSV57275923; called by muse, mutect2, varscan2
- NUDT13 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV61969825; called by muse, mutect2, varscan2
- NUTM2F | c.1475C>T p.T492I | Missense Mutation (SNP) | VAF 115/289 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1182615780, COSV53559817; called by muse, mutect2, varscan2
- OBSCN | c.2956C>G p.Q986E | Missense Mutation (SNP) | VAF 138/154 reads (90%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.814); catalogued as COSV52817228; called by muse, mutect2, varscan2
- ODF4 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 57/65 reads (88%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV60272776; called by muse, mutect2, varscan2
- ODR4 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs996539979, COSV55219093; called by muse, mutect2, varscan2
- OPN1LW | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 67/74 reads (91%) | catalogued as COSV64065195; called by muse, mutect2, varscan2
- OR10H4 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59061375; called by muse, mutect2, varscan2
- OR10Q1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 63/108 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV57471669; called by muse, mutect2, varscan2
- OR11H6 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV59644923; called by muse, mutect2, varscan2
- OR4B1 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV58883736; called by muse, mutect2, varscan2
- OR4E2 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 81/263 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57732211; called by muse, mutect2, varscan2
- OR51B6 | c.673G>A p.G225S | Missense Mutation (SNP) | VAF 93/175 reads (53%) | SIFT tolerated (0.93); PolyPhen benign (0.125); catalogued as COSV66513794; called by muse, mutect2, varscan2
- OR51E2 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as rs565364663, COSV67806631, COSV67806703, COSV67807925; called by muse, mutect2, varscan2
- OR52E4 | c.838C>A p.L280M | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as COSV57625885; called by muse, mutect2, varscan2
- OR52M1 | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.257); catalogued as COSV100798557, COSV64172590, COSV64173152; called by muse, mutect2, varscan2
- OR5AK2 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 235/419 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV58805219; called by muse, mutect2, varscan2
- OR5K1 | c.918G>A p.M306I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV60305161; called by muse, mutect2, varscan2
- OR5L2 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 189/538 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs376554037, COSV65724286; called by muse, mutect2, varscan2
- OR5M10 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as rs1319042945, COSV73242333, COSV73242415; called by muse, mutect2, varscan2
- OR5P2 | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV61491146; called by muse, mutect2, varscan2
- OR8G5 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); catalogued as COSV100422312; called by muse, mutect2, varscan2
- OR8J3 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs577731580, COSV56879327, COSV56883610; called by muse, mutect2, varscan2
- OVOL2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs748722687, COSV53861822; called by muse, mutect2, varscan2
- OXSR1 | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 61/125 reads (49%) | catalogued as rs769847615, COSV61258101, COSV61260214; called by muse, mutect2, varscan2
- P4HTM | c.1220G>A p.G407E (on ENST00000383729 / NM_177939.3; = p.G468E on NM_177938.2) | Missense Mutation (SNP) | VAF 131/240 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59088849; called by muse, mutect2, varscan2
- PADI3 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774174483, COSV64935217, COSV64935481; called by muse, mutect2, varscan2
- PALMD | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54166352; called by muse, mutect2, varscan2
- PC | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58922653; called by muse, mutect2, varscan2
- PCDH12 | c.2053T>G p.L685V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51523929; called by muse, mutect2, varscan2
- PCDHA4 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.084); catalogued as COSV63544848; called by muse, mutect2, varscan2
- PCDHA7 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 177/428 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as COSV65343559; called by muse, mutect2, varscan2
- PCDHB8 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 94/785 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.036); catalogued as rs781927716, COSV50806039; called by muse, mutect2, varscan2
- PCDHGA2 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 110/247 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); catalogued as COSV54013692; called by muse, mutect2, varscan2
- PIGK | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773098452, COSV63063331; called by muse, mutect2, varscan2
- PKHD1L1 | c.5459G>A p.G1820D | Missense Mutation (SNP) | VAF 90/97 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs772181606, COSV65750710; called by muse, mutect2, varscan2
- PLAAT5 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 151/232 reads (65%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.573); catalogued as COSV57138195; called by muse, mutect2, varscan2
- PLCE1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767766247, COSV53338884; called by muse, mutect2, varscan2
- PLEKHA1 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs772298288, COSV64570186; called by muse, mutect2, varscan2
- PLEKHG2 | c.3562G>A p.D1188N | Missense Mutation (SNP) | VAF 112/386 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.984); catalogued as COSV52688764; called by muse, mutect2, varscan2
- PODXL | c.1627G>A p.D543N (on ENST00000378555 / NM_001018111.3; = p.D511N on NM_005397.4) | Missense Mutation (SNP) | VAF 84/148 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59872423; called by muse, mutect2, varscan2
- POLE | c.3968C>T p.A1323V | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.231); catalogued as rs550525366, COSV100265795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POU4F3 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57944740; called by muse, mutect2, varscan2
- PPL | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.859); catalogued as rs1356024089, COSV62050126; called by muse, mutect2, varscan2
- PRDM7 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 108/255 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57987718; called by muse, mutect2, varscan2
- PRICKLE1 | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 311/499 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs150766064, COSV58208901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRPF6 | c.441G>A p.R147= | Splice Region (SNP) | VAF 76/142 reads (54%) | catalogued as COSV53873121, COSV53877173; called by muse, mutect2, varscan2
- PRPF6 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV53877181, COSV99411594; called by muse, mutect2, varscan2
- PRSS48 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758937723, COSV71614136; called by muse, varscan2
- PRSS54 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs753895790, COSV54685039; called by muse, mutect2, varscan2
- PSD3 | c.1235A>G p.E412G | Missense Mutation (SNP) | VAF 119/194 reads (61%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.4); catalogued as COSV58977202; called by muse, mutect2, varscan2
- PSG4 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 116/322 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs769047324, COSV54938968, COSV99737771; called by muse, mutect2, varscan2
- PTCHD3 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.225); catalogued as COSV71257221; called by muse, mutect2, varscan2
- PTPDC1 | c.1124G>A p.R375K (on ENST00000375360 / NM_177995.3; = p.R427K on NM_152422.4) | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV56625826; called by muse, mutect2, varscan2
- PTPRH | c.538C>G p.P180A | Missense Mutation (SNP) | VAF 202/330 reads (61%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.742); catalogued as COSV54749030; called by muse, mutect2, varscan2
- PTPRK | c.2227C>T p.P743S (on ENST00000368215 / NM_001291984.2; = p.P744S on NM_002844.4) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as COSV63905119; called by muse, mutect2, varscan2
- PTPRT | c.2643G>A p.M881I | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61960695; called by muse, mutect2, varscan2
- PXDNL | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 55/63 reads (87%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as COSV62496540; called by muse, mutect2, varscan2
- PXYLP1 | c.1355T>A p.L452* | Nonsense Mutation (SNP) | VAF 106/161 reads (66%) | catalogued as COSV53892605; called by muse, mutect2, varscan2
- RAD51AP2 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV67588925; called by muse, mutect2, varscan2
- RAG1 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs866525367, BM1314768, COSV55027616; called by muse, mutect2, varscan2
- RALGDS | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV64429264; called by muse, mutect2, varscan2
- RARB | c.575G>A p.R192Q (on ENST00000383772 / NM_001290216.2; = p.R185Q on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/148 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs1248786630, COSV58070379; called by muse, mutect2, varscan2
- RARG | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.026); catalogued as rs766890278, COSV57240057; called by muse, mutect2, varscan2
- RFTN1 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 169/542 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1453606633, COSV61922422; called by muse, mutect2, varscan2
- RGL3 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV66510969; called by muse, mutect2, varscan2
- RHOF | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 190/320 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs781097211, COSV57363812; called by muse, mutect2, varscan2
- RIN1 | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 124/193 reads (64%) | catalogued as COSV60928438; called by muse, mutect2, varscan2
- RRH | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58492430; called by muse, mutect2, varscan2
- RUFY4 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751955461, COSV60248029; called by muse, mutect2, varscan2
- RUNX1T1 | c.1780G>A p.G594R (on ENST00000265814 / NM_001198628.1; = p.G567R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.264); catalogued as COSV56160327; called by muse, mutect2, varscan2
- RYR1 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 103/340 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760949575, COSV62107920; called by muse, mutect2, varscan2
- RYR1 | c.3922C>T p.P1308S | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV62107927; called by muse, mutect2, varscan2
- RYR2 | c.10996C>T p.Q3666* | Nonsense Mutation (SNP) | VAF 32/242 reads (13%) | catalogued as COSV63707885; called by muse, mutect2, varscan2
- SAMD11 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV58990397; called by muse, mutect2, varscan2
- SBNO2 | c.1577T>C p.L526P | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV62322936; called by muse, mutect2, varscan2
- SCAI | c.868T>C p.F290L (on ENST00000336505 / NM_001144877.3; = p.F313L on NM_173690.5) | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60616950; called by muse, mutect2, varscan2
- SCN10A | c.3499G>A p.G1167R | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71862511; called by muse, mutect2, varscan2
- SCN11A | c.5216T>A p.I1739N | Missense Mutation (SNP) | VAF 155/269 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV56576556; called by muse, mutect2, varscan2
- SEC24C | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 91/206 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs766975550, COSV59544412; called by muse, mutect2, varscan2
- SELENOT | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV101517704; called by muse, mutect2, varscan2
- SEMA3E | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57105110; called by muse, mutect2, varscan2
- SEPTIN9 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 151/161 reads (94%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.986); catalogued as COSV70728462; called by muse, mutect2, varscan2
- SERPINB2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as rs267605232, COSV55094349; called by muse, mutect2, varscan2
- SESN2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99455524; called by muse, mutect2, varscan2
- SESN2 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs769937470, COSV99455529; called by muse, mutect2, varscan2
- SETBP1 | c.1889C>G p.A630G | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.28); catalogued as COSV56320263, COSV56334249; called by muse, mutect2, varscan2
- SHANK1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53260001; called by muse, mutect2, varscan2
- SHOC1 | c.2141G>A p.G714E | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV59506337; called by muse, mutect2, varscan2
- SIGLEC1 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407927852, COSV52470631; called by muse, mutect2, varscan2
- SIGLEC10 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.792); catalogued as COSV59485786; called by muse, mutect2, varscan2
- SIM1 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as rs754625496, COSV53491160; called by muse, mutect2, varscan2
- SIPA1L1 | c.4316G>A p.S1439N | Missense Mutation (SNP) | VAF 119/198 reads (60%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); catalogued as COSV62168654; called by muse, mutect2, varscan2
- SLC12A6 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV100825672, COSV62547124; called by muse, mutect2, varscan2
- SLC16A12 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV57950326, COSV57953759; called by muse, mutect2, varscan2
- SLC25A53 | c.369G>T p.M123I | Missense Mutation (SNP) | VAF 124/136 reads (91%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV62460481; called by muse, mutect2, varscan2
- SLC35G6 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 102/114 reads (89%) | SIFT tolerated (0.89); PolyPhen benign (0.019); catalogued as COSV59495279; called by muse, mutect2, varscan2
- SLC45A4 | c.1712C>T p.T571I (on ENST00000517878 / NM_001286646.2; = p.T520I on NM_001080431.2) | Missense Mutation (SNP) | VAF 105/117 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50170043; called by muse, mutect2, varscan2
- SLC6A13 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58257343; called by muse, mutect2, varscan2
- SLC8A1 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV60493698, COSV60500482; called by muse, mutect2, varscan2
- SLITRK4 | c.2092C>T p.H698Y | Missense Mutation (SNP) | VAF 64/69 reads (93%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.658); catalogued as COSV62025795; called by muse, mutect2, varscan2
- SMC3 | c.127T>C p.Y43H | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.957); catalogued as COSV62419599, COSV62421956; called by muse, mutect2, varscan2
- SOCS4 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1566757517, COSV59461747; called by muse, mutect2, varscan2
- SP140 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV59454066; called by muse, mutect2, varscan2
- SPIRE2 | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV65557313; called by muse, mutect2, varscan2
- SPRR2G | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 167/253 reads (66%) | PolyPhen benign (0.01); catalogued as COSV64203355; called by muse, mutect2, varscan2
- SRARP | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as COSV61497984; called by muse, mutect2, varscan2
- SRGAP2 | c.2852C>T p.S951L (on ENST00000624873 / NM_001170637.4; = p.S952L on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs781890702, COSV55342079; called by muse, mutect2, varscan2
- STAT1 | c.1735A>C p.M579L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV63117222; called by muse, mutect2, varscan2
- STRAP | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs145164927; called by muse, mutect2, varscan2
- SWT1 | c.1836C>T p.I612= | Splice Region (SNP) | VAF 21/97 reads (22%) | catalogued as COSV62258445; called by muse, mutect2, varscan2
- SYDE2 | c.1048T>A p.L350I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.057); catalogued as COSV52317690; called by muse, mutect2, varscan2
- SYNE1 | c.2569G>A p.E857K (on ENST00000367255 / NM_182961.4; = p.E864K on NM_033071.3) | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV55075763; called by muse, mutect2, varscan2
- SYT12 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as COSV67354769; called by muse, mutect2, varscan2
- SYT17 | c.871G>C p.G291R | Missense Mutation (SNP) | VAF 158/350 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62547818; called by muse, mutect2, varscan2
- TBR1 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 91/181 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67419011; called by muse, mutect2, varscan2
- TCN2 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs774428161, COSV53192280; called by muse, mutect2, varscan2
- TCOF1 | c.2809G>A p.E937K (on ENST00000377797 / NM_001135243.1; = p.E860K on NM_000356.4) | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.967); catalogued as rs372917861; called by muse, mutect2, varscan2
- TECTA | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 164/187 reads (88%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50783931; called by muse, mutect2, varscan2
- TEP1 | c.4718A>G p.E1573G | Missense Mutation (SNP) | VAF 58/225 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV52998413; called by muse, mutect2, varscan2
- TEP1 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52998431; called by muse, mutect2, varscan2
- TESMIN | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99663483; called by muse, mutect2, varscan2
- TESMIN | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99663485, COSV99663605; called by muse, mutect2, varscan2
- THBS3 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 380/525 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64250644; called by muse, mutect2, varscan2
- THEMIS | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.453); catalogued as rs1279803297, COSV64073736; called by muse, mutect2, varscan2
- THY1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 66/71 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs868606739, COSV52455108; called by muse, mutect2, varscan2
- TIAM2 | c.5027G>A p.G1676E (on ENST00000529824; = p.G1647E on NM_012454.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.995); catalogued as COSV51643247; called by muse, mutect2, varscan2
- TLR10 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV58301890; called by muse, mutect2, varscan2
- TLR5 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 149/202 reads (74%) | SIFT tolerated (0.64); PolyPhen benign (0.041); catalogued as rs139394912; called by muse, mutect2, varscan2
- TMED7 | c.173A>G p.K58R | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.372); catalogued as COSV56696123; called by muse, mutect2, varscan2
- TMEM183A | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs966185999, COSV65887977; called by muse, mutect2, varscan2
- TMEM8B | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 114/211 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV65077685; called by muse, mutect2, varscan2
- TMPRSS13 | c.1220C>T p.T407I | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs1400800268, COSV99070565; called by muse, mutect2, varscan2
- TNN | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1023950568, COSV53433677; called by muse, mutect2, varscan2
- TOR3A | c.659T>G p.I220S | Missense Mutation (SNP) | VAF 88/146 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV61680729; called by muse, mutect2, varscan2
- TRAPPC3 | c.347T>G p.V116G | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64264558; called by muse, mutect2, varscan2
- TRIM45 | c.1175T>A p.I392N | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56714659; called by muse, mutect2, varscan2
- TRIM6 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.96); catalogued as rs1214852302, COSV104376274, COSV53478516; called by muse, mutect2, varscan2
- TRIM69 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.054); catalogued as COSV57805105; called by muse, mutect2, varscan2
- TRIM69 | c.808C>T p.L270F (on ENST00000329464 / NM_182985.5; = p.L111F on NM_080745.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57805114; called by muse, mutect2, varscan2
- TRPC3 | c.1693C>T p.L565F (on ENST00000379645 / NM_001366479.2; = p.L492F on NM_003305.2) | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.222); catalogued as COSV53383566, COSV99312466; called by muse, mutect2, varscan2
- TRPM1 | c.701T>C p.I234T | Missense Mutation (SNP) | VAF 100/253 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs1342680878, COSV56640563; called by muse, mutect2, varscan2
- TRPM4 | c.3559G>A p.G1187R | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV53267688; called by muse, mutect2, varscan2
- TRPM6 | c.5504G>A p.R1835K | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62520482, COSV62524004; called by muse, mutect2, varscan2
- TTN | c.12211C>T p.P4071S (on ENST00000591111; = p.P4025S on NM_003319.4) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100601525; called by muse, mutect2, varscan2
- TXNDC11 | c.2306C>T p.P769L (on ENST00000356957 / NM_001303447.2; = p.P742L on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51602325; called by muse, mutect2, varscan2
- TXNDC5 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0.025); catalogued as COSV51671328; called by muse, mutect2, varscan2
- UBR5 | c.5407C>T p.P1803S | Missense Mutation (SNP) | VAF 127/142 reads (89%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as rs1353508525, COSV55297135; called by muse, mutect2, varscan2
- UFC1 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 57/309 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57090787; called by muse, mutect2, varscan2
- UGT1A4 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 153/433 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759057764, COSV100530005; called by muse, mutect2, varscan2
- UNC13A | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 21/38 reads (55%) | catalogued as COSV53191502; called by muse, mutect2, varscan2
- USH1G | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 86/96 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752343151, COSV58883368; called by muse, mutect2, varscan2
- USP6NL | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53214732; called by muse, mutect2, varscan2
- VAPB | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV55668322; called by muse, mutect2, varscan2
- VWA3B | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as rs1469313622, COSV68246038; called by muse, mutect2, varscan2
- VWA8 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 44/44 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV55703451; called by muse, mutect2, varscan2
- VWF | c.2085G>A p.M695I | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1565844846, COSV54631684; called by muse, mutect2, varscan2
- WDR31 | c.632C>T p.T211I (on ENST00000374193 / NM_001006615.3; = p.T210I on NM_145241.5) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100516645; called by muse, mutect2, varscan2
- WDR47 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 104/247 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63059385; called by muse, mutect2, varscan2
- WDR49 | c.1268C>T p.S423L (on ENST00000308378 / NM_001366158.1; = p.S764L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs747703419, COSV57705394, COSV57708425; called by muse, mutect2, varscan2
- WDR90 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 281/654 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53474282; called by muse, mutect2, varscan2
- WNT2 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55412844; called by muse, mutect2, varscan2
- XDH | c.3519+1G>A p.X1173_splice | Splice Site (SNP) | VAF 47/96 reads (49%) | catalogued as COSV65150810; called by muse, mutect2, varscan2
- XIRP2 | c.496C>T p.H166Y (on ENST00000628543; = p.H341Y on NM_152381.6) | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.418); catalogued as COSV54728150, COSV54741680; called by muse, mutect2, varscan2
- XYLT1 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377021125; called by muse, mutect2, varscan2
- YBX2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 110/120 reads (92%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV50302092; called by muse, mutect2, varscan2
- ZDHHC8 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100272470; called by muse, mutect2, varscan2
- ZFHX3 | c.4177G>T p.V1393L | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV51731827; called by muse, mutect2, varscan2
- ZFHX3 | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.186); catalogued as rs765294332, COSV51711517, COSV51731842; called by muse, mutect2, varscan2
- ZGRF1 | c.2768C>T p.P923L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV52202784; called by muse, mutect2, varscan2
- ZMYM5 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 170/185 reads (92%) | SIFT tolerated (0.14); PolyPhen benign (0.216); catalogued as COSV61989700; called by muse, mutect2, varscan2
- ZNF195 | c.1730C>T p.P577L (on ENST00000399602 / NM_001130520.3; = p.P505L on NM_007152.5) | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV50004355; called by muse, mutect2, varscan2
- ZNF285 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 94/162 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV58410545; called by muse, mutect2, varscan2
- ZNF479 | c.1459C>T p.H487Y | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV58642760; called by muse, mutect2, varscan2
- ZNF503 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs756210383, COSV65307769; called by muse, mutect2
- ZNF609 | c.3617C>T p.P1206L | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as COSV58588929; called by muse, mutect2, varscan2
- ZNF626 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782429235, COSV74130597; called by muse, mutect2, varscan2
- ZNF775 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.756); catalogued as COSV61614201; called by muse, mutect2, varscan2
- ZNF782 | c.451A>T p.M151L | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56654561; called by muse, mutect2, varscan2
- ZNF786 | c.2080C>T p.H694Y | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60277507; called by muse, mutect2, varscan2
- ZNF846 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV67412520; called by muse, mutect2, varscan2
- ZRSR2 | c.458G>A p.W153* | Nonsense Mutation (SNP) | VAF 91/100 reads (91%) | catalogued as COSV57067041; called by muse, mutect2, varscan2
- ZSCAN20 | c.2956C>T p.P986S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1360425474, COSV63683131; called by muse, mutect2, varscan2
- ZSWIM2 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 55/143 reads (38%) | catalogued as COSV54573647; called by muse, mutect2, varscan2
- FOXD4L6 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); called by mutect2, varscan2
- IGHV1-3 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IGHV4-61 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- LY75 | c.2275C>T p.H759Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- MAPK8IP3 | c.2792del p.P931Rfs*68 | Frame Shift Del (DEL) | VAF 29/72 reads (40%) | called by mutect2, pindel, varscan2
- PTPN11 | c.1218dup p.G407Wfs*39 | Frame Shift Ins (INS) | VAF 39/175 reads (22%) | called by mutect2, pindel, varscan2
- RHBDL1 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by mutect2, varscan2
- SPG11 | c.5547_5550delinsAAA p.N1850Kfs*6 | Frame Shift Del (DEL) | VAF 40/145 reads (28%) | called by pindel, varscan2*
- TRAV27 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- TSEN15 | c.372_373del p.K124Nfs*8 | Frame Shift Del (DEL) | VAF 28/135 reads (21%) | called by mutect2, pindel, varscan2
- ZNF347 | c.454del p.Y152Tfs*6 | Frame Shift Del (DEL) | VAF 143/294 reads (49%) | called by mutect2, pindel, varscan2
- ABCG4 | c.1359C>T p.F453= | Silent (SNP) | VAF 360/400 reads (90%) | catalogued as rs747993546, COSV56645345; called by muse, mutect2, varscan2
- AC104389.6 | c.420C>T p.F140= | Silent (SNP) | VAF 80/225 reads (36%) | catalogued as rs374656432; called by muse, mutect2, varscan2
- ADAM2 | c.1884T>C p.N628= | Silent (SNP) | VAF 67/224 reads (30%) | catalogued as COSV55867085; called by muse, mutect2, varscan2
- ADCY1 | c.513C>T p.F171= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV52040908; called by muse, mutect2, varscan2
- ADGRB3 | c.4047C>T p.F1349= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV53257263; called by muse, mutect2, varscan2
- ADGRF2 | c.1290C>T p.T430= (on ENST00000296862 / NM_001368115.2; = p.T362= on NM_153839.7) | Silent (SNP) | VAF 68/150 reads (45%) | catalogued as COSV57289567, COSV57291294; called by muse, mutect2, varscan2
- AKAP3 | c.660C>T p.I220= | Silent (SNP) | VAF 53/179 reads (30%) | catalogued as COSV57419650; called by muse, mutect2, varscan2
- AL121899.2 | c.1593G>A p.T531= | Silent (SNP) | VAF 45/74 reads (61%) | catalogued as COSV67350362; called by muse, mutect2, varscan2
- APOBEC3C | c.321C>T p.F107= | Silent (SNP) | VAF 269/442 reads (61%) | catalogued as COSV53328268; called by muse, mutect2, varscan2
- ARHGAP22 | c.1293C>T p.S431= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV50943745; called by muse, mutect2, varscan2
- ASAH2 | c.732C>T p.F244= | Silent (SNP) | VAF 113/270 reads (42%) | called by muse, mutect2, varscan2
- ASPG | c.384C>T p.F128= | Silent (SNP) | VAF 67/120 reads (56%) | catalogued as COSV71934085; called by muse, mutect2, varscan2
- AUTS2 | c.1794C>T p.G598= | Silent (SNP) | VAF 128/258 reads (50%) | catalogued as COSV61388068; called by muse, mutect2, varscan2
- BCLAF3 | c.387T>C p.S129= | Silent (SNP) | VAF 93/102 reads (91%) | catalogued as COSV61414817; called by muse, mutect2, varscan2
- BDKRB2 | c.1164G>A p.G388= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as rs1566697467, COSV60016642; called by muse, mutect2, varscan2
- BEND3 | c.1200C>T p.F400= | Silent (SNP) | VAF 95/192 reads (49%) | catalogued as rs782719486, COSV64682042; called by muse, mutect2, varscan2
- BRD1 | c.753C>T p.I251= | Silent (SNP) | VAF 34/59 reads (58%) | catalogued as COSV53460814; called by muse, mutect2, varscan2
- CA6 | c.162G>A p.R54= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV66262811; called by muse, mutect2
- CACNA1A | c.1554C>T p.F518= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV64210000; called by muse, mutect2, varscan2
- CACNA1I | c.4864C>T p.L1622= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV60816367; called by muse, mutect2, varscan2
- CACNA1S | c.1710C>T p.I570= | Silent (SNP) | VAF 85/383 reads (22%) | catalogued as COSV62942842; called by muse, mutect2, varscan2
- CAPN11 | c.1560C>T p.I520= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as rs1420349837, COSV67239120; called by muse, mutect2, varscan2
- CAST | c.465T>G p.A155= (on ENST00000341926; = p.A238= on NM_001750.7 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 47/220 reads (21%) | catalogued as COSV57788823; called by muse, mutect2, varscan2
- CCDC102B | c.1449G>A p.L483= | Silent (SNP) | VAF 38/54 reads (70%) | catalogued as COSV60151970; called by muse, mutect2, varscan2
- CD163L1 | c.3612C>T p.F1204= | Silent (SNP) | VAF 143/249 reads (57%) | catalogued as rs767456913, COSV58019256; called by muse, mutect2, varscan2
- CD6 | c.846C>T p.F282= | Silent (SNP) | VAF 103/165 reads (62%) | catalogued as COSV57841653; called by muse, mutect2, varscan2
- CDH9 | c.1956C>T p.V652= | Silent (SNP) | VAF 71/130 reads (55%) | catalogued as COSV50404369; called by muse, mutect2, varscan2
- CES4A | c.990C>T p.D330= | Silent (SNP) | VAF 99/220 reads (45%) | catalogued as rs1264805584, COSV58657867, COSV58658138; called by muse, mutect2, varscan2
- CFH | c.3663G>A p.G1221= | Silent (SNP) | VAF 37/245 reads (15%) | catalogued as rs772150552, COSV66412160; called by muse, mutect2, varscan2
- CFTR | c.2172C>T p.I724= | Silent (SNP) | VAF 43/70 reads (61%) | catalogued as rs368599862; called by muse, mutect2, varscan2
- CHD2 | c.2743T>C p.L915= | Silent (SNP) | VAF 228/383 reads (60%) | catalogued as rs112279925, COSV67713571; called by muse, mutect2, varscan2
- CHD4 | c.2784C>T p.D928= (on ENST00000357008 / NM_001363606.2; = p.D941= on NM_001273.5) | Silent (SNP) | VAF 37/179 reads (21%) | catalogued as rs747303727, COSV100537585; called by muse, mutect2, varscan2
- CHL1 | c.1326C>T p.F442= (on ENST00000397491 / NM_001253387.1; = p.F458= on NM_006614.4) | Silent (SNP) | VAF 131/222 reads (59%) | catalogued as COSV56603660, COSV99851470; called by muse, mutect2, varscan2
- CLN3 | c.483C>T p.S161= (on ENST00000360019 / NM_001286104.2; = p.S185= on NM_000086.2) | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100343174; called by muse, mutect2, varscan2
- CNTNAP1 | c.735A>T p.P245= | Silent (SNP) | VAF 226/253 reads (89%) | catalogued as COSV52853660; called by muse, mutect2, varscan2
- CSMD2 | c.1689G>A p.K563= | Silent (SNP) | VAF 65/184 reads (35%) | catalogued as COSV53952147; called by muse, mutect2, varscan2
- CUEDC1 | c.1128C>T p.P376= | Silent (SNP) | VAF 85/93 reads (91%) | catalogued as COSV64227138; called by muse, mutect2, varscan2
- CXorf58 | c.459G>A p.R153= | Silent (SNP) | VAF 58/64 reads (91%) | catalogued as COSV64858751; called by muse, mutect2, varscan2
- CYP3A7 | c.1245C>T p.L415= | Silent (SNP) | VAF 61/130 reads (47%) | catalogued as COSV100312604; called by muse, mutect2, varscan2
- DACT1 | c.2262C>T p.F754= | Silent (SNP) | VAF 131/433 reads (30%) | catalogued as rs1348608093, COSV60020646; called by muse, mutect2, varscan2
- DCAF8L1 | c.1419C>T p.I473= | Silent (SNP) | VAF 20/21 reads (95%) | catalogued as COSV71595483; called by muse, mutect2, varscan2
- DDIT4 | c.487C>T p.L163= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as COSV56578035; called by muse, mutect2, varscan2
- DISP1 | c.2415G>A p.K805= | Silent (SNP) | VAF 47/79 reads (59%) | catalogued as COSV52663893; called by muse, mutect2, varscan2
- DMRTB1 | c.681C>T p.A227= | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as rs774222053, COSV65113853; called by muse, mutect2, varscan2
- DNAH5 | c.4494G>A p.R1498= | Silent (SNP) | VAF 56/94 reads (60%) | catalogued as COSV54246689; called by muse, mutect2, varscan2
- DVL3 | c.1545C>T p.A515= | Silent (SNP) | VAF 84/267 reads (31%) | catalogued as rs1393901782, COSV53049880, COSV53050287; called by muse, mutect2, varscan2
- DYTN | c.927G>A p.Q309= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV71751803; called by muse, mutect2, varscan2
- EBF1 | c.1260A>G p.Q420= | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as rs780793034, COSV58191433; called by muse, mutect2, varscan2
- EHD1 | c.1113C>T p.F371= | Silent (SNP) | VAF 487/780 reads (62%) | catalogued as rs1371162565, COSV57736357; called by muse, mutect2, varscan2
- ELF2 | c.45T>C p.L15= | Silent (SNP) | VAF 88/202 reads (44%) | catalogued as COSV55495171; called by muse, mutect2, varscan2
- ELP4 | c.1017C>T p.N339= (on ENST00000350638; = p.N338= on NM_019040.5) | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs749321679, COSV63357489; called by muse, mutect2, varscan2
- EMILIN1 | c.681G>C p.A227= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV53156765; called by muse, mutect2, varscan2
- EML4 | c.2682A>G p.Q894= | Silent (SNP) | VAF 65/140 reads (46%) | catalogued as rs1244653419, COSV59303885; called by muse, mutect2, varscan2
- ENTPD6 | c.243C>T p.A81= | Silent (SNP) | VAF 76/140 reads (54%) | catalogued as rs1408405601, COSV61752267; called by muse, mutect2, varscan2
- EPHA3 | c.957C>T p.S319= | Silent (SNP) | VAF 189/326 reads (58%) | catalogued as COSV100349489, COSV60706921; called by muse, mutect2, varscan2
- ERGIC3 | c.612C>T p.F204= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs780955750, COSV54140264; called by muse, mutect2, varscan2
- FBXO27 | c.657C>T p.F219= | Silent (SNP) | VAF 139/466 reads (30%) | catalogued as COSV53072881, COSV53073029; called by muse, mutect2, varscan2
- FNIP1 | c.2067A>G p.V689= | Silent (SNP) | VAF 149/504 reads (30%) | catalogued as COSV57199719; called by muse, mutect2, varscan2
- FRAS1 | c.9618C>T p.F3206= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV53613783; called by muse, mutect2, varscan2
- FRAS1 | c.9732C>T p.P3244= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as rs756958123, COSV53639601; called by muse, mutect2, varscan2
- FRMPD2 | c.1851C>T p.V617= | Silent (SNP) | VAF 77/192 reads (40%) | catalogued as COSV59722545; called by muse, mutect2, varscan2
- FYB2 | c.1986G>A p.E662= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV58588364; called by muse, mutect2, varscan2
- GCA | c.615C>T p.F205= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV52026610; called by muse, mutect2, varscan2
- GDE1 | c.469C>T p.L157= | Silent (SNP) | VAF 62/170 reads (36%) | catalogued as COSV100783142, COSV62059846; called by muse, mutect2, varscan2
- GFOD1 | c.384C>T p.F128= | Silent (SNP) | VAF 185/295 reads (63%) | catalogued as rs966200224, COSV64954809; called by muse, mutect2, varscan2
- GFRAL | c.291T>G p.L97= | Silent (SNP) | VAF 58/124 reads (47%) | catalogued as COSV61234547; called by muse, mutect2, varscan2
- GPHN | c.1623G>A p.T541= (on ENST00000315266 / NM_001377519.1; = p.T574= on NM_020806.5) | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs774161949, COSV59490728; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR4 | c.561C>T p.F187= | Silent (SNP) | VAF 55/168 reads (33%) | catalogued as COSV59918042; called by muse, mutect2, varscan2
- GRIN2A | c.3426C>T p.P1142= | Silent (SNP) | VAF 99/191 reads (52%) | catalogued as rs150487431, COSV58024254, COSV58037713; ClinVar: likely benign; called by muse, mutect2, varscan2
- HCRTR2 | c.900G>A p.R300= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV63798517; called by muse, mutect2
- HHIPL2 | c.1329G>A p.G443= | Silent (SNP) | VAF 61/296 reads (21%) | catalogued as COSV58567211; called by muse, mutect2, varscan2
- HYDIN | c.15012C>T p.I5004= | Silent (SNP) | VAF 75/189 reads (40%) | catalogued as rs1404124047, COSV66637454; called by muse, mutect2, varscan2
- IFIT1 | c.480C>T p.A160= | Silent (SNP) | VAF 56/118 reads (47%) | catalogued as rs1240450052, COSV65661720; called by muse, mutect2
- IL36RN | c.160C>T p.L54= | Silent (SNP) | VAF 65/157 reads (41%) | catalogued as rs763641466, COSV61010841, COSV61010917; called by muse, mutect2, varscan2
- IQCA1 | c.2241C>T p.V747= | Silent (SNP) | VAF 58/139 reads (42%) | catalogued as rs190664020, COSV54510795; called by muse, mutect2, varscan2
- KCNG2 | c.303C>T p.F101= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV60269955; called by muse, mutect2
- KCNK10 | c.183G>A p.G61= | Silent (SNP) | VAF 96/315 reads (30%) | catalogued as COSV56650994; called by muse, mutect2, varscan2
- KCNQ3 | c.2472G>A p.S824= | Silent (SNP) | VAF 54/63 reads (86%) | catalogued as rs774287489, COSV66473419, COSV66484458; called by muse, mutect2, varscan2
- KCTD17 | c.351C>T p.I117= | Silent (SNP) | VAF 45/136 reads (33%) | catalogued as rs372826685; called by muse, mutect2, varscan2
- KIF18B | c.813G>A p.L271= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV59273347; called by muse, mutect2, varscan2
- KLHL8 | c.1587C>T p.P529= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs1183203314, COSV99911291; called by muse, mutect2, varscan2
- KRT71 | c.93C>T p.S31= | Silent (SNP) | VAF 243/420 reads (58%) | catalogued as COSV57292544; called by muse, mutect2, varscan2
- LAMA2 | c.3621C>T p.T1207= | Silent (SNP) | VAF 50/154 reads (32%) | catalogued as rs1240538348, COSV101370255; called by muse, varscan2
- MAPK8IP2 | c.1710C>T p.L570= | Silent (SNP) | VAF 111/199 reads (56%) | catalogued as rs1254284646, COSV50507868; called by muse, mutect2, varscan2
- MCM7 | c.813C>T p.V271= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as rs767764393, COSV57998507; called by muse, mutect2, varscan2
- MEGF8 | c.1869C>T p.A623= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV52098555; called by muse, mutect2, varscan2
- MET | c.2055G>A p.G685= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as rs766401668, COSV59267302; called by muse, mutect2, varscan2
- METAP1D | c.390G>A p.R130= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as rs773766497, COSV59931943; called by muse, mutect2, varscan2
- MICAL2 | c.105C>T p.L35= | Silent (SNP) | VAF 67/132 reads (51%) | catalogued as rs748738037, COSV56315921, COSV56325126; called by muse, mutect2, varscan2
- MLH1 | c.1563C>T p.L521= | Silent (SNP) | VAF 87/139 reads (63%) | catalogued as COSV51623265; called by muse, mutect2, varscan2
- MMP13 | c.369G>A p.V123= | Silent (SNP) | VAF 51/56 reads (91%) | catalogued as COSV52825282; called by muse, mutect2, varscan2
- MMP9 | c.1650G>A p.P550= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100812375; called by muse, mutect2, varscan2
- MON1B | c.591C>T p.I197= | Silent (SNP) | VAF 86/180 reads (48%) | catalogued as rs775602347, COSV50245904; called by muse, mutect2, varscan2
- MREG | c.642C>T p.P214= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV54375512; called by muse, mutect2, varscan2
- MROH2B | c.2298C>T p.V766= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV68180875; called by muse, mutect2, varscan2
- MSTN | c.976C>T p.L326= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV53621923; called by muse, mutect2, varscan2
- MYH3 | c.3021C>T p.A1007= | Silent (SNP) | VAF 49/53 reads (92%) | catalogued as COSV56869074; called by muse, mutect2, varscan2
- MYH6 | c.1797G>A p.K599= | Silent (SNP) | VAF 51/189 reads (27%) | catalogued as COSV62453818; called by muse, mutect2, varscan2
- MYO18A | c.1416C>T p.P472= | Silent (SNP) | VAF 32/36 reads (89%) | catalogued as COSV62872225; called by muse, mutect2, varscan2
- MYO1H | c.1797C>T p.I599= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs754880718, COSV60449820; called by muse, mutect2, varscan2
- MYO7B | c.2238C>T p.F746= | Silent (SNP) | VAF 68/161 reads (42%) | catalogued as COSV67350994; called by muse, mutect2, varscan2
- NAV3 | c.4200C>T p.L1400= | Silent (SNP) | VAF 73/261 reads (28%) | catalogued as rs374863435; called by muse, mutect2, varscan2
- NEBL | c.744T>G p.P248= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as rs1461808223, COSV65805274; called by muse, varscan2
- NEBL | c.300C>T p.I100= | Silent (SNP) | VAF 68/163 reads (42%) | catalogued as rs370924189; called by muse, mutect2, varscan2
- NEUROD1 | c.549G>A p.L183= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as rs1487394350, COSV54550820; called by muse, mutect2, varscan2
- NOTCH1 | c.5358C>T p.P1786= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV53084030; called by muse, mutect2, varscan2
- NRXN1 | c.525G>A p.R175= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1297054425, COSV68040574; called by muse, mutect2, varscan2
- OLFML2A | c.1794C>T p.V598= | Silent (SNP) | VAF 65/135 reads (48%) | catalogued as rs755547468, COSV56585188; called by muse, mutect2, varscan2
- OR10W1 | c.477C>T p.F159= | Silent (SNP) | VAF 36/56 reads (64%) | catalogued as COSV67720803; called by muse, mutect2, varscan2
- OR11H1 | c.913C>T p.L305= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs1192701526; called by mutect2, varscan2
- OR13C5 | c.733C>T p.L245= | Silent (SNP) | VAF 69/144 reads (48%) | catalogued as rs1250130934, COSV66165245; called by muse, mutect2, varscan2
- OR2A25 | c.94C>T p.L32= | Silent (SNP) | VAF 60/191 reads (31%) | catalogued as COSV68717593; called by muse, mutect2, varscan2
- OR51E1 | c.771C>T p.F257= | Silent (SNP) | VAF 116/262 reads (44%) | catalogued as COSV67810806; called by muse, mutect2, varscan2
- OR52N5 | c.405T>A p.I135= | Silent (SNP) | VAF 92/182 reads (51%) | catalogued as COSV57699366; called by muse, mutect2, varscan2
- OR6C65 | c.432C>T p.I144= | Silent (SNP) | VAF 142/241 reads (59%) | catalogued as COSV65569254; called by muse, mutect2, varscan2
- OSBP | c.1728G>A p.K576= | Silent (SNP) | VAF 64/214 reads (30%) | catalogued as COSV55662322, COSV55665159; called by muse, mutect2, varscan2
- OXCT2 | c.1374C>T p.T458= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as rs770152248, COSV59594547; called by muse, mutect2, varscan2
- P4HA3 | c.459C>T p.G153= | Silent (SNP) | VAF 244/267 reads (91%) | catalogued as COSV59043622; called by muse, mutect2, varscan2
- PCDHA3 | c.930C>T p.F310= | Silent (SNP) | VAF 64/166 reads (39%) | catalogued as rs868926378, COSV63540440; called by muse, mutect2
- PCDHB2 | c.2307G>A p.L769= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as COSV99164467; called by muse, mutect2, varscan2
- PCDHGB3 | c.1506G>A p.S502= | Silent (SNP) | VAF 85/195 reads (44%) | catalogued as rs370015318; called by muse, mutect2, varscan2
- PEF1 | c.768C>T p.A256= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as COSV65484217; called by muse, mutect2, varscan2
- PGPEP1L | c.30C>T p.S10= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs748597267, COSV66709868; called by muse, mutect2
- PHF20 | c.2634C>T p.S878= | Silent (SNP) | VAF 43/179 reads (24%) | catalogued as COSV64977380; called by muse, mutect2, varscan2
- PI4K2B | c.1374T>C p.G458= | Silent (SNP) | VAF 57/111 reads (51%) | catalogued as COSV53512781; called by muse, mutect2, varscan2
- PKD1L1 | c.2550C>T p.S850= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as COSV56959811; called by muse, mutect2, varscan2
- PLOD3 | c.2202C>A p.S734= | Silent (SNP) | VAF 89/320 reads (28%) | catalogued as COSV56185361; called by muse, mutect2, varscan2
- POLE | c.3969C>T p.A1323= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as COSV100265794; called by muse, mutect2, varscan2
- POTEH | c.567C>T p.V189= | Silent (SNP) | VAF 33/202 reads (16%) | catalogued as rs771299802, COSV100624809, COSV100624830; called by muse, mutect2, varscan2
- PPP1R13L | c.2418G>A p.Q806= | Silent (SNP) | VAF 88/316 reads (28%) | catalogued as COSV62909449; called by muse, mutect2, varscan2
- PPP2R2C | c.1173G>A p.R391= | Silent (SNP) | VAF 43/69 reads (62%) | catalogued as COSV59447091; called by muse, mutect2, varscan2
- PPP2R2C | c.714C>T p.F238= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs749169351, COSV58670868; called by muse, mutect2, varscan2
- PRAG1 | c.1428C>T p.V476= | Silent (SNP) | VAF 86/140 reads (61%) | catalogued as COSV58165677; called by muse, mutect2, varscan2
- PRKAG3 | c.492G>A p.Q164= | Silent (SNP) | VAF 56/129 reads (43%) | catalogued as COSV52103452; called by muse, mutect2, varscan2
- PRKCQ | c.273G>A p.S91= | Silent (SNP) | VAF 70/199 reads (35%) | catalogued as rs758517186, COSV54117517; called by muse, mutect2, varscan2
- PROKR2 | c.798G>A p.R266= | Silent (SNP) | VAF 59/102 reads (58%) | catalogued as COSV54088781; called by muse, mutect2, varscan2
- PSG3 | c.276G>A p.G92= | Silent (SNP) | VAF 209/863 reads (24%) | catalogued as rs758972252, COSV59506455; called by muse, mutect2, varscan2
- PSMD3 | c.1083C>T p.F361= | Silent (SNP) | VAF 168/185 reads (91%) | catalogued as COSV52856564; called by muse, mutect2, varscan2
- PTPRE | c.1041G>A p.V347= | Silent (SNP) | VAF 122/305 reads (40%) | catalogued as COSV54557445; called by muse, mutect2, varscan2
- PXDNL | c.228G>A p.L76= | Silent (SNP) | VAF 29/30 reads (97%) | catalogued as COSV62496543; called by muse, mutect2, varscan2
- PZP | c.2332C>T p.L778= | Silent (SNP) | VAF 80/262 reads (31%) | catalogued as rs753188815, COSV54353981, COSV54368495; called by muse, mutect2, varscan2
- RPL18A | c.57C>T p.T19= | Silent (SNP) | VAF 39/80 reads (49%) | catalogued as COSV55830715; called by muse, mutect2, varscan2
- RSPH10B2 | c.228C>T p.S76= | Silent (SNP) | VAF 176/531 reads (33%) | catalogued as rs757172534, COSV51871101; called by muse, mutect2, varscan2
- S100Z | c.15C>T p.L5= | Silent (SNP) | VAF 44/59 reads (75%) | catalogued as rs747413826, COSV58255948; called by muse, mutect2, varscan2
- S1PR4 | c.357C>T p.F119= | Silent (SNP) | VAF 62/191 reads (32%) | catalogued as COSV55739608; called by muse, mutect2, varscan2
- SBF2 | c.3345C>T p.F1115= | Silent (SNP) | VAF 143/326 reads (44%) | catalogued as COSV56308495; called by muse, mutect2, varscan2
- SCN10A | c.2247G>A p.K749= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as rs762907750, COSV101479409, COSV71862512; called by muse, mutect2, varscan2
- SDR42E1 | c.138C>T p.T46= | Silent (SNP) | VAF 95/233 reads (41%) | catalogued as COSV61094985; called by muse, mutect2, varscan2
- SEC14L5 | c.1686C>T p.A562= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as COSV52041281; called by muse, mutect2, varscan2
- SEC14L5 | c.2004C>T p.S668= | Silent (SNP) | VAF 62/124 reads (50%) | catalogued as rs1035362785, COSV52041289, COSV99228983; called by muse, mutect2, varscan2
- SELENOT | c.57C>T p.A19= | Silent (SNP) | VAF 46/62 reads (74%) | catalogued as COSV101517705; called by muse, mutect2, varscan2
- SELP | c.726G>A p.L242= | Silent (SNP) | VAF 47/219 reads (21%) | catalogued as COSV55256920; called by muse, mutect2, varscan2
- SKI | c.1137C>T p.F379= | Silent (SNP) | VAF 210/473 reads (44%) | catalogued as COSV66014481; called by muse, mutect2, varscan2
- SLC12A8 | c.906G>A p.A302= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs770799482, COSV58869749; called by muse, mutect2, varscan2
- SLC1A4 | c.1284C>T p.V428= | Silent (SNP) | VAF 65/141 reads (46%) | catalogued as COSV52235734; called by muse, mutect2, varscan2
- SLC27A3 | c.1257C>T p.T419= (on ENST00000271857; = p.T291= on NM_024330.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 83/131 reads (63%) | catalogued as COSV55165316; called by muse, mutect2, varscan2
- SLC38A1 | c.1323C>T p.I441= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV67064706; called by muse, mutect2, varscan2
- SNTN | c.201C>T p.F67= | Silent (SNP) | VAF 53/215 reads (25%) | catalogued as COSV59539712; called by muse, mutect2, varscan2
- SREBF2 | c.1914C>T p.L638= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV63332240; called by muse, mutect2, varscan2
- SRXN1 | c.285C>T p.S95= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV67938169; called by muse, mutect2, varscan2
- SSTR2 | c.1014G>A p.G338= | Silent (SNP) | VAF 94/100 reads (94%) | catalogued as rs1266481029, COSV59535891; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.876C>T p.I292= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as rs776913825, COSV59130501; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.282G>A p.R94= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV100603126, COSV59570718; called by muse, mutect2, varscan2
- STK17A | c.1068C>T p.T356= | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as rs763752720, COSV60048431; called by muse, mutect2, varscan2
- SYNE1 | c.3351G>A p.R1117= (on ENST00000367255 / NM_182961.4; = p.R1124= on NM_033071.3) | Silent (SNP) | VAF 141/352 reads (40%) | catalogued as COSV55075717; called by muse, mutect2, varscan2
- TAS2R10 | c.597C>T p.S199= | Silent (SNP) | VAF 58/107 reads (54%) | catalogued as COSV53701578; called by muse, mutect2, varscan2
- TBC1D9B | c.774C>T p.F258= | Silent (SNP) | VAF 48/86 reads (56%) | catalogued as COSV62283592; called by muse, mutect2, varscan2
- TEK | c.333C>T p.I111= | Silent (SNP) | VAF 73/176 reads (41%) | catalogued as COSV66232587; called by muse, mutect2, varscan2
- TIA1 | c.141C>T p.P47= | Silent (SNP) | VAF 56/135 reads (41%) | catalogued as COSV57008095; called by muse, mutect2, varscan2
- TMEM14A | c.93T>A p.A31= | Silent (SNP) | VAF 52/114 reads (46%) | catalogued as COSV52987124; called by muse, mutect2, varscan2
- TMEM202 | c.63G>A p.G21= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV58983505; called by muse, mutect2, varscan2
- TMPRSS13 | c.1221C>T p.T407= | Silent (SNP) | VAF 12/12 reads (100%) | catalogued as rs771095961, COSV101471403, COSV101471434; called by muse, varscan2
- TNR | c.423C>T p.I141= | Silent (SNP) | VAF 86/352 reads (24%) | catalogued as rs1215247478, COSV54877160; called by muse, mutect2, varscan2
- TNS3 | c.2166C>T p.A722= | Silent (SNP) | VAF 180/306 reads (59%) | catalogued as COSV60797264; called by muse, mutect2, varscan2
- TREM1 | c.594C>T p.I198= | Silent (SNP) | VAF 99/106 reads (93%) | catalogued as COSV55149443, COSV99776387; called by muse, mutect2, varscan2
- TRIM21 | c.867C>T p.I289= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV54345963; called by muse, mutect2, varscan2
- TRIM5 | c.1062C>T p.I354= | Silent (SNP) | VAF 161/367 reads (44%) | catalogued as COSV59901979; called by muse, mutect2, varscan2
- TRPC3 | c.1692C>T p.F564= (on ENST00000379645 / NM_001366479.2; = p.F491= on NM_003305.2) | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV99312324; called by muse, mutect2, varscan2
- TSR3 | c.390C>T p.D130= | Silent (SNP) | VAF 59/164 reads (36%) | catalogued as rs143210621, COSV50105124; called by muse, mutect2, varscan2
- TTC12 | c.756T>A p.L252= | Silent (SNP) | VAF 204/224 reads (91%) | catalogued as COSV59099651; called by muse, mutect2, varscan2
- TTC29 | c.306C>T p.S102= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs201492631, COSV57283491; called by muse, mutect2, varscan2
- ULK1 | c.3003G>A p.E1001= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV58859511; called by muse, mutect2, varscan2
- USP34 | c.2448C>T p.L816= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as rs779664561, COSV68402757, COSV68405238; called by muse, mutect2, varscan2
- UTP18 | c.1611C>T p.A537= | Silent (SNP) | VAF 38/45 reads (84%) | catalogued as rs754573465, COSV56584904; called by muse, mutect2, varscan2
- VASN | c.147C>T p.D49= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1436122254, COSV52033304; called by muse, mutect2, varscan2
- VHL | c.279C>T p.G93= | Silent (SNP) | VAF 51/98 reads (52%) | catalogued as CD003987, COSV56560256, COSV99845972; called by muse, mutect2, varscan2
- WDR31 | c.633C>T p.T211= (on ENST00000374193 / NM_001006615.3; = p.T210= on NM_145241.5) | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV100516644; called by muse, mutect2, varscan2
- XYLT1 | c.1725C>T p.S575= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV54494328; called by muse, mutect2, varscan2
- ZAN | c.5688C>T p.S1896= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs144009891; called by muse, mutect2, varscan2
- ZDHHC8 | c.699C>T p.T233= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV57710162; called by muse, mutect2, varscan2
- ZIM3 | c.1077G>A p.G359= | Silent (SNP) | VAF 123/233 reads (53%) | catalogued as rs1462667966, COSV54142069; called by muse, mutect2, varscan2
- ZNF212 | c.939C>T p.S313= | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as COSV60025919; called by muse, mutect2, varscan2
- ZNF527 | c.1104C>T p.S368= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV62234339; called by muse, mutect2, varscan2
- ZNF718 | c.1080C>T p.I360= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs781907136, COSV68140609; called by muse, mutect2, varscan2
- ZNF79 | c.213C>T p.S71= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV61071700; called by muse, mutect2, varscan2
- ABCA3 | c.-173C>T | 5'UTR (SNP) | VAF 20/36 reads (56%) | catalogued as rs774331733, COSV100068187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668152 G>A | 5'Flank (SNP) | VAF 139/241 reads (58%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851783 G>A | 3'Flank (SNP) | VAF 62/69 reads (90%) | called by muse, mutect2, varscan2
- BIRC8 | n.1059G>A | RNA (SNP) | VAF 43/75 reads (57%) | catalogued as COSV70347753; called by muse, mutect2, varscan2
- DCX | c.-22-398G>A | Intron (SNP) | VAF 127/139 reads (91%) | catalogued as COSV57574352; called by muse, mutect2, varscan2
- ESPN | chr1:6460106 G>A | 3'Flank (SNP) | VAF 40/59 reads (68%) | catalogued as rs761979450, COSV61069418, COSV61069475; called by muse, mutect2, varscan2
- MIR1185-2 | n.51G>A | RNA (SNP) | VAF 37/147 reads (25%) | catalogued as rs1311369211; called by muse, mutect2, varscan2
- OSGIN1 | n.967G>A | RNA (SNP) | VAF 38/104 reads (37%) | catalogued as rs751481333, COSV59676793; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185137G>C | Intron (SNP) | VAF 104/224 reads (46%) | catalogued as rs771567004, COSV60946776, COSV60951877; called by muse, mutect2, varscan2
- RBM44 | c.-98-2209C>T | Intron (SNP) | VAF 15/27 reads (56%) | catalogued as COSV57632683; called by muse, mutect2, varscan2
- SNORD115-19 | n.36G>A | RNA (SNP) | VAF 109/357 reads (31%) | called by muse, mutect2, varscan2
- TYMS | c.205+39G>A | Intron (SNP) | VAF 14/19 reads (74%) | catalogued as COSV60075920; called by muse, mutect2, varscan2
- USH1C | c.*11G>A | 3'UTR (SNP) | VAF 25/54 reads (46%) | catalogued as rs779265996, COSV50014893; called by muse, mutect2, varscan2
